Somatic mutation profile of tumor specimen C3N-01847-02 (aliquot CPT0098920009) from CPTAC case C3N-01847, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.6 years (21,027 days).
Specimen C3N-01847-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f16881d-42ca-4fa2-89da-351c3801c04b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01847-31 (Blood Derived Normal), aliquot CPT0098950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31b51a16-2685-40d4-b602-b43dcebf9837

The open-access MAF lists 88 somatic variants for this specimen: 58 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 26, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAL | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 25/268 reads (9%) | catalogued as rs398122928, CM1212077, COSV52333874; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 116/361 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 25/183 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1266405480; called by muse, mutect2, varscan2
- ARHGAP9 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.644); catalogued as rs774931853, COSV57364199, COSV57366562; called by muse, mutect2, varscan2
- BPNT2 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV52907472; called by muse, mutect2
- C1QL4 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760481550; called by muse, mutect2, varscan2
- CSF1R | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53839048; called by muse, mutect2
- CSMD3 | c.10249C>A p.P3417T (on ENST00000297405 / NM_001363185.1; = p.P3248T on NM_052900.3) | Missense Mutation (SNP) | VAF 35/351 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs919848950, COSV99843997; called by muse, mutect2
- DMP1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 71/672 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373457215, COSV99218638; called by muse, mutect2, varscan2
- DVL3 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs76594728, COSV57458079; called by mutect2, varscan2
- EDA | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs780456712, COSV58879051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR142 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs375980809; called by muse, mutect2, varscan2
- KIF2B | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 98/411 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214581422, COSV52130895; called by muse, mutect2, varscan2
- LIM2 | c.232G>A p.G78S (on ENST00000596399 / NM_001161748.2; = p.G120S on NM_030657.4) | Missense Mutation (SNP) | VAF 50/425 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1568480816; called by muse, mutect2, varscan2
- MUC5B | c.9395C>A p.T3132N | Missense Mutation (SNP) | VAF 90/477 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV71593699; called by muse, mutect2, varscan2
- MYC | c.130G>A p.A44T (on ENST00000377970; = p.A59T on NM_002467.6) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52371326; called by muse, mutect2
- MYC | c.1076A>G p.H359R (on ENST00000377970; = p.H374R on NM_002467.6) | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367783; called by muse, mutect2, varscan2
- MYO15A | c.9883C>T p.R3295C | Missense Mutation (SNP) | VAF 63/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775389608, COSV52755815; called by muse, mutect2, varscan2
- OR8A1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.034); catalogued as rs781403924, COSV52507977; called by muse, mutect2, varscan2
- PCP4L1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV73440594; called by muse, mutect2, varscan2
- PTCHD3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs374816927, COSV71257213; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 126/286 reads (44%) | catalogued as rs146650273; called by pindel, varscan2
- RHD | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs141615605; called by muse, mutect2, varscan2
- RYR1 | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 59/570 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as rs372800648; called by muse, mutect2, varscan2
- SARDH | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375124485, COSV64098519; called by muse, mutect2, varscan2
- SCD5 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1352862495, COSV100124534; called by muse, mutect2, varscan2
- SDK2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746724792, COSV66193172, COSV66197263; called by mutect2, varscan2
- SEPTIN4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs779427385; called by muse, mutect2, varscan2
- SLFN11 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 90/440 reads (20%) | catalogued as rs150159511, COSV104413370; called by muse, mutect2, varscan2
- SPTAN1 | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 69/592 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1161676352, COSV63985329; called by muse, mutect2, varscan2
- TBC1D10A | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762103249, COSV53163259; called by muse, mutect2, varscan2
- XXYLT1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100118859; called by muse, mutect2, varscan2
- ZIC1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51554228; called by muse, mutect2, varscan2
- ZNF648 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.446); catalogued as COSV60569637; called by muse, mutect2
- AFF1 | c.1126A>C p.T376P | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARID1A | c.6749_6750del p.E2250Vfs*27 | Frame Shift Del (DEL) | VAF 15/149 reads (10%) | called by pindel, varscan2
- ATP11C | c.2054A>T p.K685I | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- BAHCC1 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- CCDC134 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- CLEC3A | c.120G>T p.K40N (on ENST00000651443; = p.K31N on NM_005752.6) | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DENND4C | c.4679G>A p.W1560* (on ENST00000434457 / NM_001330640.2; = p.W1511* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- FBXO31 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GRIA3 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LRRC38 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NLRP2 | c.2367-1G>T p.X789_splice | Splice Site (SNP) | VAF 78/373 reads (21%) | called by muse, mutect2, varscan2
- OR2L5 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); called by muse, mutect2
- OTOG | c.5375A>G p.D1792G | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PIGG | c.276C>A p.Y92* | Nonsense Mutation (SNP) | VAF 35/419 reads (8%) | called by muse, mutect2
- PIRT | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- PKD1 | c.11839G>C p.A3947P (on ENST00000262304 / NM_001009944.3; = p.A3946P on NM_000296.4) | Missense Mutation (SNP) | VAF 68/327 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRNP | c.371dup p.L125Pfs*20 | Frame Shift Ins (INS) | VAF 52/487 reads (11%) | called by mutect2, varscan2
- RBM15 | c.2087T>A p.L696* | Nonsense Mutation (SNP) | VAF 19/280 reads (7%) | called by muse, mutect2
- SOX17 | c.428dup p.Q144Afs*18 | Frame Shift Ins (INS) | VAF 18/138 reads (13%) | called by mutect2, pindel, varscan2
- TEX13C | c.241A>G p.R81G | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TTC7A | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZFP92 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZMYM1 | c.2581del p.C861Vfs*2 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- ALS2 | c.1653G>A p.L551= | Silent (SNP) | VAF 117/507 reads (23%) | called by muse, mutect2, varscan2
- AMER2 | c.1617C>T p.S539= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV63439717; called by muse, mutect2
- ARHGAP21 | c.4911C>T p.S1637= | Silent (SNP) | VAF 67/342 reads (20%) | catalogued as rs755395699; called by muse, mutect2, varscan2
- ATP13A2 | c.2481G>A p.G827= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as rs761620417; called by muse, mutect2, varscan2
- CCNB3 | c.4173G>A p.Q1391= | Silent (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2
- CDH5 | c.312C>T p.A104= | Silent (SNP) | VAF 26/377 reads (7%) | called by muse, mutect2
- CEBPE | c.303G>A p.A101= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs149752323; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTN3 | c.900G>A p.E300= | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as COSV99723371; called by muse, mutect2, varscan2
- DDN | c.1740C>T p.A580= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- DPP3 | c.1164C>T p.A388= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs200352856, COSV64757637; called by muse, mutect2, varscan2
- FRMPD4 | c.2241C>T p.D747= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs769972556, COSV66216986; called by muse, mutect2, varscan2
- GJB5 | c.420C>T p.S140= | Silent (SNP) | VAF 56/482 reads (12%) | catalogued as rs554960310, COSV58355869; called by muse, mutect2, varscan2
- GUCY1A2 | c.2076G>T p.G692= | Silent (SNP) | VAF 38/478 reads (8%) | called by muse, mutect2
- IQCA1 | c.264C>T p.N88= | Silent (SNP) | VAF 36/254 reads (14%) | catalogued as rs770400268; called by muse, mutect2, varscan2
- KAZN | c.222G>A p.L74= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- MSR1 | c.99T>A p.P33= | Silent (SNP) | VAF 48/368 reads (13%) | called by muse, mutect2, varscan2
- NDN | c.747C>T p.R249= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV59361679; called by muse, mutect2, varscan2
- NEFM | c.936C>T p.S312= | Silent (SNP) | VAF 36/282 reads (13%) | catalogued as COSV55332784; called by muse, mutect2, varscan2
- PCDHB15 | c.642G>A p.A214= | Silent (SNP) | VAF 29/241 reads (12%) | called by muse, mutect2, varscan2
- PLD2 | c.2559C>T p.N853= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as rs774751573, COSV54007082; called by muse, mutect2, varscan2
- RBFOX1 | c.771G>A p.P257= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as rs916986800, COSV60959742; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHD | c.18G>A p.P6= | Silent (SNP) | VAF 18/266 reads (7%) | catalogued as rs752685469; called by muse, mutect2
- RYR1 | c.5499C>T p.S1833= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as COSV100615419; called by muse, mutect2, varscan2
- SHANK2 | c.2568A>G p.L856= | Silent (SNP) | VAF 28/380 reads (7%) | called by muse, mutect2
- TMEM175 | c.975C>T p.F325= | Silent (SNP) | VAF 43/252 reads (17%) | catalogued as rs747062611, COSV53277541; called by muse, mutect2, varscan2
- WDR45 | c.6T>G p.T2= | Silent (SNP) | VAF 34/306 reads (11%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.262C>T | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158863 G>A | 5'Flank (SNP) | VAF 32/129 reads (25%) | catalogued as rs981333486; called by muse, mutect2, varscan2
- RNY4P30 | chr13:49890762 T>A | 5'Flank (SNP) | VAF 54/363 reads (15%) | called by muse, mutect2, varscan2
- ZNF727 | c.-90C>T | 5'UTR (SNP) | VAF 12/327 reads (4%) | catalogued as COSV71646738; called by muse, mutect2
